Somatic mutation profile of tumor specimen TCGA-B6-A1KI-01A (aliquot TCGA-B6-A1KI-01A-11D-A14K-09) from TCGA case TCGA-B6-A1KI, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 63.1 years (23,031 days).
Specimen TCGA-B6-A1KI-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9d4bb505-560b-4726-8101-7bf8206a8a24.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B6-A1KI-10A (Blood Derived Normal), aliquot TCGA-B6-A1KI-10A-01W-A16I-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4e196797-6ca9-4546-bfd5-3d36ac69e7b9

The open-access MAF lists 22 somatic variants for this specimen: 15 protein-altering or splice-affecting, 7 silent.
By variant classification: Missense Mutation 12, Silent 7, Frame Shift Del 2, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KLF4 | c.1225A>C p.K409Q | Missense Mutation (SNP) | VAF 223/410 reads (54%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.749); catalogued as COSV65928521; called by muse, mutect2, varscan2
- PIK3CA | c.1637A>C p.Q546P | Missense Mutation (SNP) | VAF 33/102 reads (32%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs397517201, COSV55875400, COSV55876869, COSV55877455; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCA5 | c.4715C>T p.P1572L | Missense Mutation (SNP) | VAF 24/106 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs930791779, COSV67019021; called by muse, mutect2, varscan2
- ABHD1 | c.428T>C p.L143P | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1210980768, COSV53208163; called by muse, mutect2, varscan2
- CATSPER3 | c.1141C>G p.L381V | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.991); catalogued as COSV50950075; called by muse, mutect2, varscan2
- EXT2 | c.713C>T p.A238V (on ENST00000343631; = p.A271V on NM_000401.3) | Missense Mutation (SNP) | VAF 18/170 reads (11%) | SIFT tolerated (0.27); PolyPhen benign (0.007); catalogued as COSV100640666; called by muse, mutect2, varscan2
- GPX2 | c.243G>C p.E81D | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV63036689; called by mutect2, varscan2
- MAGI2 | c.2773C>T p.R925C | Missense Mutation (SNP) | VAF 33/126 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1410794318, COSV100835426, COSV62692532; called by muse, mutect2, varscan2
- MAP3K1 | c.2208del p.Y736* | Frame Shift Del (DEL) | VAF 80/277 reads (29%) | catalogued as COSV68127323; called by mutect2, pindel, varscan2
- MEIOC | c.742C>A p.H248N | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.036); catalogued as COSV63441467; called by muse, mutect2, varscan2
- OR8K3 | c.32A>T p.E11V | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.796); catalogued as COSV57133022; called by muse, mutect2, varscan2
- PLK4 | c.1112G>A p.R371Q | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs961446130, COSV54637142; called by muse, mutect2
- XXYLT1 | c.724T>C p.F242L | Missense Mutation (SNP) | VAF 10/77 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); catalogued as COSV59988069; called by muse, mutect2, varscan2
- EPB41 | c.1059del p.F353Lfs*25 (on ENST00000343067 / NM_001166005.2; = p.F144Lfs*25 on NM_004437.4) | Frame Shift Del (DEL) | VAF 34/133 reads (26%) | called by mutect2, pindel, varscan2
- ESR1 | c.1351_1356del p.I451_I452del | In Frame Del (DEL) | VAF 41/261 reads (16%) | called by mutect2, pindel, varscan2
- ADAMTS3 | c.2676G>A p.P892= | Silent (SNP) | VAF 55/264 reads (21%) | catalogued as rs200265826; called by muse, mutect2, varscan2
- ANKRD35 | c.204A>G p.E68= | Silent (SNP) | VAF 12/96 reads (13%) | catalogued as COSV62911563; called by muse, mutect2, varscan2
- ATP11A | c.2532C>G p.G844= | Silent (SNP) | VAF 28/133 reads (21%) | catalogued as COSV52124100; called by muse, mutect2, varscan2
- CLPTM1L | c.885G>A p.A295= | Silent (SNP) | VAF 18/81 reads (22%) | catalogued as rs368342519; called by muse, mutect2, varscan2
- PCDHGA2 | c.2415G>A p.T805= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as COSV54014664; called by muse, mutect2, varscan2
- RET | c.1908G>A p.T636= | Silent (SNP) | VAF 8/46 reads (17%) | catalogued as rs886038663, COSV60702826; ClinVar: likely benign; called by mutect2, varscan2
- TLE3 | c.1521C>T p.G507= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as COSV58174373; called by muse, mutect2, varscan2
